Somatic mutation profile of cancer-model specimen HCM-BROD-0644-C25-85M (3D Organoid, passage 6; aliquot HCM-BROD-0644-C25-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0644-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.7 years (25,096 days).
Specimen HCM-BROD-0644-C25-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a16bd19-c499-4daf-9f0d-b8c5d939b8c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0644-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0644-C25-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/807053cd-433b-414c-972d-b5933aff4a5f

The open-access MAF lists 92 somatic variants for this specimen: 68 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Nonsense Mutation 6, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 2, 5'Flank 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.389T>A p.L130Q | Missense Mutation (SNP) | VAF 946/948 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV58685390, COSV58696112, COSV58702833, COSV58725016; called by muse, mutect2, varscan2
- CHD3 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 300/300 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1567856331; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 202/642 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 286/440 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.96+1G>T p.X32_splice | Splice Site (SNP) | VAF 332/334 reads (99%) | hotspot (GDC flag); catalogued as rs1131691003, CS167193, COSV52662718, COSV52757202, COSV53162510; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACTN3 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 375/569 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV72207521; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 134/530 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs148746108; called by muse, mutect2, varscan2
- ARID1B | c.6430G>T p.G2144* | Nonsense Mutation (SNP) | VAF 315/620 reads (51%) | catalogued as rs1161111557; called by muse, mutect2, varscan2
- ASTN1 | c.1960G>A p.D654N | Missense Mutation (SNP) | VAF 291/515 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763625810, COSV56063069, COSV99922679; called by muse, mutect2, varscan2
- BRSK1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 227/639 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752984665, COSV58668321, COSV58669350; called by muse, mutect2, varscan2
- CDCP1 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.862); catalogued as rs199848700; called by muse, mutect2, varscan2
- CTNNA2 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 179/435 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); catalogued as rs141412774, COSV63578466; called by muse, mutect2, varscan2
- FAM160A1 | c.2722_2725del p.L908Ifs*7 | Frame Shift Del (DEL) | VAF 121/241 reads (50%) | catalogued as rs752320854; called by mutect2, pindel, varscan2
- FGA | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 392/393 reads (100%) | catalogued as COSV57400687; called by muse, mutect2, varscan2
- HDX | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 84/128 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868328516, COSV52976258, COSV52981132; called by muse, mutect2, varscan2
- HERC2 | c.4496G>A p.G1499D | Missense Mutation (SNP) | VAF 40/459 reads (9%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs763287026, COSV99870323; called by muse, mutect2
- IGHE | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 563/866 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs781850078; called by muse, varscan2
- IGHM | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 119/651 reads (18%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.691); catalogued as rs751188409; called by muse, mutect2, varscan2
- MERTK | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 164/361 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773270603; called by muse, mutect2, varscan2
- MINDY4B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 124/434 reads (29%) | catalogued as rs759419116; called by muse, mutect2, varscan2
- MPDZ | c.827C>A p.A276E | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV59942337; called by muse, mutect2, varscan2
- NOX4 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 111/450 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1358349700; called by muse, mutect2, varscan2
- OR10G6 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 156/513 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs771526853; called by muse, mutect2, varscan2
- OR5H15 | c.496C>A p.L166I | Missense Mutation (SNP) | VAF 170/325 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV62949354; called by muse, mutect2, varscan2
- PLSCR5 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 304/474 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs559124176; called by muse, varscan2
- PRKAR2A | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 212/426 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769798310, COSV55553115; called by muse, mutect2, varscan2
- ROCK1 | c.362dup p.W122Lfs*25 | Frame Shift Ins (INS) | VAF 91/434 reads (21%) | catalogued as rs35810558; called by mutect2, pindel, varscan2
- SASH1 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752157549, COSV66558671, COSV66564030; called by muse, mutect2, varscan2
- SDK1 | c.5743G>A p.A1915T | Missense Mutation (SNP) | VAF 304/305 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs754648325; called by muse, mutect2, varscan2
- SFMBT2 | c.2290C>T p.R764W | Missense Mutation (SNP) | VAF 740/1131 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs767296309, COSV100738611; called by muse, mutect2, varscan2
- SH3TC1 | c.3237C>G p.I1079M | Missense Mutation (SNP) | VAF 286/286 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs752719231; called by muse, mutect2, varscan2
- SKOR2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 208/680 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101247438; called by muse, mutect2, varscan2
- SLC9A5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 643/1097 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762466239, COSV55361960; called by muse, mutect2, varscan2
- SPOUT1 | c.196_198del p.K66del | In Frame Del (DEL) | VAF 152/326 reads (47%) | catalogued as rs1372380049; called by mutect2, pindel, varscan2
- SRFBP1 | c.1274T>A p.I425N | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs745456471, COSV59583127; called by muse, mutect2, varscan2
- SYDE2 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 307/623 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs766453212; called by muse, mutect2, varscan2
- TBX19 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 207/417 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs772489505, COSV63197104; called by muse, mutect2, varscan2
- TRHDE | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 212/989 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs1268997017, COSV53838461; called by muse, mutect2, varscan2
- WDR97 | c.4123G>A p.A1375T | Missense Mutation (SNP) | VAF 498/794 reads (63%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.089); catalogued as rs372718448; called by muse, mutect2
- ZNF513 | c.1465C>T p.R489C | Missense Mutation (SNP) | VAF 270/645 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52009673; called by muse, mutect2, varscan2
- ZNF98 | c.305dup p.N102Kfs*12 | Frame Shift Ins (INS) | VAF 40/86 reads (47%) | catalogued as rs757764317; called by mutect2, varscan2
- CD46 | c.1142A>G p.D381G | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN6 | c.1853G>A p.W618* | Nonsense Mutation (SNP) | VAF 114/286 reads (40%) | called by muse, mutect2, varscan2
- DPYSL5 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 58/698 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.313); called by muse, mutect2
- GRAMD4 | c.807C>G p.A269= | Splice Region (SNP) | VAF 257/420 reads (61%) | called by muse, mutect2, varscan2
- IDH3A | c.234G>A p.W78* | Nonsense Mutation (SNP) | VAF 146/524 reads (28%) | called by muse, mutect2, varscan2
- KCNH1 | c.1268C>T p.A423V (on ENST00000271751 / NM_172362.3; = p.A396V on NM_002238.4) | Missense Mutation (SNP) | VAF 276/543 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- KCP | c.2467C>T p.P823S (on ENST00000620378; = p.P883S on NM_001366122.1) | Missense Mutation (SNP) | VAF 430/430 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCTD20 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 440/440 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KREMEN2 | c.547_548dup p.R184Dfs*170 | Frame Shift Ins (INS) | VAF 516/930 reads (55%) | called by mutect2, pindel, varscan2
- LRP1B | c.8033A>G p.N2678S | Missense Mutation (SNP) | VAF 92/186 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- LRRC4C | c.818A>C p.N273T | Missense Mutation (SNP) | VAF 26/691 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MEGF8 | c.5950G>C p.E1984Q (on ENST00000251268 / NM_001271938.2; = p.E1917Q on NM_001410.3) | Missense Mutation (SNP) | VAF 536/879 reads (61%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- NLGN1 | c.562A>C p.T188P | Missense Mutation (SNP) | VAF 88/458 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- PARD6G | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 663/999 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZRN4 | c.1117C>A p.P373T (on ENST00000402685 / NM_001164595.2; = p.P115T on NM_013377.4) | Missense Mutation (SNP) | VAF 156/156 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POLD2 | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 274/607 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRRC2B | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 22/391 reads (6%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.492); called by muse, mutect2
- RNF43 | c.314_316del p.S105del | In Frame Del (DEL) | VAF 300/303 reads (99%) | called by mutect2, pindel, varscan2
- S1PR5 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 830/831 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SETD2 | c.760del p.T254Lfs*10 | Frame Shift Del (DEL) | VAF 137/379 reads (36%) | called by mutect2, pindel, varscan2
- SLC4A1 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 622/634 reads (98%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- STYXL2 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 173/405 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAS2R13 | c.401T>A p.L134Q | Missense Mutation (SNP) | VAF 139/501 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TRIM49 | c.155G>T p.C52F | Missense Mutation (SNP) | VAF 299/967 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXN2 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 240/865 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC1 | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 568/1586 reads (36%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- ZNF554 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 315/317 reads (99%) | called by muse, mutect2, varscan2
- ACTN3 | c.1926C>T p.N642= | Silent (SNP) | VAF 529/793 reads (67%) | catalogued as rs368786615; called by muse, mutect2, varscan2
- CADPS | c.3600C>T p.D1200= | Silent (SNP) | VAF 81/217 reads (37%) | catalogued as rs376866233, COSV51891256; called by muse, mutect2, varscan2
- CCT8L2 | c.444C>G p.P148= | Silent (SNP) | VAF 229/438 reads (52%) | catalogued as COSV100743038; called by muse, mutect2, varscan2
- CYP3A7 | c.657C>T p.F219= | Silent (SNP) | VAF 107/327 reads (33%) | catalogued as rs375990155; called by muse, mutect2, varscan2
- FYB2 | c.1275C>A p.V425= | Silent (SNP) | VAF 181/365 reads (50%) | called by muse, mutect2, varscan2
- GPANK1 | c.693C>T p.R231= | Silent (SNP) | VAF 411/1304 reads (32%) | called by muse, mutect2, varscan2
- GSC | c.132C>T p.Y44= | Silent (SNP) | VAF 246/992 reads (25%) | catalogued as rs1446826320; called by muse, varscan2
- HAS3 | c.246G>A p.P82= | Silent (SNP) | VAF 692/1826 reads (38%) | catalogued as rs145360778; called by muse, mutect2
- IGHV4-28 | c.330G>A p.T110= | Silent (SNP) | VAF 216/367 reads (59%) | catalogued as rs781975086; called by muse, mutect2, varscan2
- IL12RB2 | c.2298G>A p.L766= | Silent (SNP) | VAF 279/617 reads (45%) | called by muse, mutect2, varscan2
- INSYN1 | c.123C>T p.R41= | Silent (SNP) | VAF 184/396 reads (46%) | catalogued as rs372544619; called by muse, mutect2, varscan2
- KIF17 | c.2781C>T p.G927= | Silent (SNP) | VAF 44/555 reads (8%) | catalogued as rs752090322; called by muse, mutect2
- KRTAP19-1 | c.252C>T p.Y84= | Silent (SNP) | VAF 133/287 reads (46%) | catalogued as rs1196043751, COSV66861156; called by muse, mutect2, varscan2
- MIS18A | c.576T>C p.L192= | Silent (SNP) | VAF 81/208 reads (39%) | catalogued as COSV51588800; called by muse, mutect2, varscan2
- NRF1 | c.1287C>T p.I429= | Silent (SNP) | VAF 236/236 reads (100%) | catalogued as rs756500940; called by muse, mutect2, varscan2
- P2RY1 | c.69G>A p.S23= | Silent (SNP) | VAF 251/846 reads (30%) | catalogued as COSV100521684; called by muse, mutect2, varscan2
- PRELP | c.627C>T p.D209= | Silent (SNP) | VAF 341/654 reads (52%) | catalogued as rs765943721, COSV58115353; called by muse, mutect2, varscan2
- PRR14 | c.1035C>T p.C345= | Silent (SNP) | VAF 510/787 reads (65%) | catalogued as COSV54911690; called by muse, mutect2, varscan2
- SLC12A5 | c.3144C>T p.S1048= (on ENST00000454036 / NM_001134771.2; = p.S1025= on NM_020708.5) | Silent (SNP) | VAF 34/589 reads (6%) | called by muse, mutect2
- TTN | c.28047T>C p.N9349= (on ENST00000591111; = p.N8422= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 192/353 reads (54%) | called by muse, mutect2, varscan2
- UBR1 | c.1458A>G p.K486= | Silent (SNP) | VAF 169/275 reads (61%) | called by muse, mutect2, varscan2
- ZNF536 | c.45G>A p.P15= | Silent (SNP) | VAF 256/822 reads (31%) | catalogued as COSV62834081; called by muse, mutect2, varscan2
- FAM122C | c.-4G>A | 5'UTR (SNP) | VAF 243/578 reads (42%) | catalogued as rs1447589944, COSV100888235, COSV100888251; called by muse, mutect2, varscan2
- GLRX2 | chr1:193105516 del CCTCCTCGCAGCTGAGCGCGTCCT | 5'Flank (DEL) | VAF 112/358 reads (31%) | called by mutect2, pindel, varscan2
